Gene-level copy-number profile of tumor specimen TCGA-3B-A9HL-01A from TCGA case TCGA-3B-A9HL, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Specified parts of peritoneum; Age at diagnosis: 67.4 years (24,628 days).
Specimen TCGA-3B-A9HL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.98c4be6d-efc5-4386-a19e-1967f146d688.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3B-A9HL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5a6ae4c7-7572-4b4b-9d27-835452605cb0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,237; copy number 2: 5,798; copy number 3: 18,587; copy number 4: 29,060; copy number 5: 2,953; copy number 6: 507; copy number 7: 720; copy number 8: 41; copy number 9: 49; copy number 10: 69; copy number 11: 93; copy number 12: 50; copy number 13: 7; copy number 14: 9; copy number 15: 109; copy number 17: 32; copy number 18: 15; copy number 19: 56; copy number 20: 2; copy number 21: 15; copy number 22: 8; copy number 23: 132; copy number 24: 23; copy number 25: 1; copy number 26: 11; copy number 27: 29; copy number 29: 10; copy number 30: 19; copy number 32: 16; copy number 33: 15; copy number 34: 9; copy number 35: 8; copy number 37: 29; copy number 38: 34; copy number 39: 4; copy number 45: 1; copy number 46: 1; copy number 48: 38; copy number 52: 14; copy number 54: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3B-A9HL-01A-11D-A386-01): tumor purity 0.66, ploidy 3.79, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 883 genes in 56 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:51,907,956–51,996,039, 4 genes, copy number 22 (within-gene range 4–22): RAB3B, RNA5SP48, AL445685.2, RN7SL290P.
- chr1:52,020,153–52,033,350, 1 gene, copy number 22 (within-gene range 4–22): AL445685.3.
- chr1:53,226,900–53,368,245, 10 genes, copy number 27 (within-gene range 4–27): MAGOH, AL606760.1, LRP8, AL355483.3, AL355483.1, AL355483.2, LINC01771, AC119428.2, AC119428.1, LINC02812.
- chr1:56,494,761–56,715,335, 5 genes, copy number 29: PLPP3, RPL21P23, RPL23AP85, AC099789.1, PRKAA2.
- chr1:58,643,440–60,149,784, 22 genes, copy number 11–24 (within-gene range 5–24): MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1, CYP2J2, RN7SL475P, C1orf87, PGBD4P8, LINC02778.
- chr1:60,659,631–60,868,009, 1 gene, copy number 33: AC099792.1.
- chr1:99,263,953–99,842,761, 9 genes, copy number 34: PLPPR4, AL365220.1, LINC01708, PALMD, HMGB3P10, FRRS1, RNU4-75P, Y_RNA, AC096949.1.
- chr1:105,433,994–105,893,517, 5 genes, copy number 11: CDK4P1, LINC01676, SEPTIN2P1, AL512844.2, AL512844.1.
- chr1:107,056,674–108,644,900, 21 genes, copy number 11 (within-gene range 4–11): PRMT6, NTNG1, NDUFA4P1, VAV3, MIR7852, VAV3-AS1, LINC02785, SLC25A24, AL359258.2, AL359258.3, NBPF4, AL359258.1, SLC25A24P1, NBPF5P, SLC25A24P2, AL390038.1, NBPF6, AL392088.2, ST13P21, AL392088.1, FAM102B.
- chr2:231,781,671–232,344,350, 9 genes, copy number 14 (within-gene range 2–14): COPS7B, RPL28P2, AC073476.2, AC073476.1, MIR1471, NPPC, DIS3L2, AC019130.1, MIR562.
- chr6:10,722,915–11,138,733, 14 genes, copy number 11 (within-gene range 8–11): TMEM14C, AL024498.1, TMEM14B, AL024498.2, RNA5SP203, MAK, GCM2, AL357497.1, SYCP2L, ELOVL2, AL121955.1, ELOVL2-AS1, SMIM13, ERVFRD-1.
- chr6:38,923,029–38,953,099, 2 genes, copy number 10 (within-gene range 5–10): DNAH8-AS1, AL034345.1.
- chr6:43,770,184–43,852,333, 5 genes, copy number 9: VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1.
- chr6:101,430,411–101,454,245, 2 genes, copy number 26: ACTG1P18, AP002528.1.
- chr6:108,798,929–117,573,571, 153 genes, copy number 11–23 (within-gene range 2–23) (broad region; genes not listed).
- chr6:132,954,257–138,904,070, 114 genes, copy number 10–37 (within-gene range 4–37) (broad region; genes not listed).
- chr12:4,012,902–5,046,788, 32 genes, copy number 23–30: AC084375.1, HSPA8P5, AC007207.1, CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6, C12orf4, RAD51AP1, DYRK4, AC005832.2, AC005832.4, AKAP3, AC005832.3, AC005832.1, NDUFA9, AC005833.1, GAU1, GALNT8, AC005833.2, KCNA6, AC006063.1, AC006063.3, AC006063.4, AC005906.2, KCNA1, AC006063.2, AC005906.1, KCNA5.
- chr12:8,597,509–9,400,387, 38 genes, copy number 23 (within-gene range 4–23): AC092184.1, AICDA, AC092184.2, HADHAP2, MFAP5, AC092490.2, AC092490.3, RIMKLB, RPSAP51, A2ML1-AS1, AC092490.1, A2ML1-AS2, A2ML1, AC006581.2, PHC1, M6PR, KLRG1, AC006581.1, HNRNPA1P34, VDAC2P2, LINC00612, A2M-AS1, A2M, KRT17P8, BTG1P1, PZP, TPT1P12, A2MP1, MIR1244-3, PTMAP4, LINC00987, AC010175.1, AC009533.1, SNORA75, AC009533.2, AC009533.3, LINC02367, AC009533.4.
- chr12:9,752,486–10,223,128, 23 genes, copy number 10–18: CD69, GCNAP1, KLRF1, CLEC2B, AC091814.1, KLRF2, CLEC2A, LINC02470, CLEC12A-AS1, CLEC12A, CLEC1B, CLEC12B, AC024224.2, CLEC9A, AC024224.1, CLEC1A, RN7SKP161, HNRNPABP1, CLEC7A, OLR1, TMEM52B, GABARAPL1, GABARAPL1-AS1.
- chr12:10,750,188–11,171,608, 13 genes, copy number 19 (within-gene range 4–19): LINC02366, HSPE1P12, TAS2R7, TAS2R8, TAS2R9, PRH1, TAS2R10, AC006518.1, PRR4, AC018630.4, AC006518.2, TAS2R13, PRH2.
- chr12:10,964,425–11,031,407, 5 genes, copy number 19: TAS2R15P, TAS2R50, TAS2R20, TAS2R19, TAS2R31.
- chr12:28,505,394–28,565,141, 2 genes, copy number 19: RNA5SP355, AC084754.1.
- chr12:57,723,761–58,920,504, 33 genes, copy number 38: AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3.
- chr12:65,466,820–65,642,372, 3 genes, copy number 33 (within-gene range 4–35): AC025419.1, AC090023.1, LINC02454.
- chr12:65,824,460–66,343,643, 19 genes, copy number 27: HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB.
- chr12:66,563,524–66,569,194, 2 genes, copy number 13: OSBPL9P5, OSBPL9P4.
- chr12:68,674,371–71,441,898, 54 genes, copy number 23–48 (within-gene range 8–48): AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8.
- chr12:71,582,293–72,186,618, 15 genes, copy number 32–54 (within-gene range 21–54): AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1.
- chr12:72,727,923–73,846,188, 8 genes, copy number 15–39: AC133480.1, AC090503.2, LINC02444, AC090503.1, AC087879.1, RNU6-1012P, LINC02445, U8.
- chr12:76,858,709–77,163,638, 5 genes, copy number 13: CSRP2, AC124784.1, AC025161.1, E2F7, AC079030.1.
- chr12:77,324,641–79,503,396, 15 genes, copy number 24–52 (within-gene range 3–52): NAV3, AC073591.1, AC138331.1, AC073571.1, PRXL2AP1, LINC02424, AC128707.1, AC130415.1, AC079362.1, AC068993.1, AC068993.2, SYT1, AC090709.1, AC027288.3, MIR1252.
- chr12:81,953,719–82,686,632, 9 genes, copy number 21: LINC02426, AC011602.1, CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1, AC091214.1.
- chr12:83,151,331–86,838,904, 21 genes, copy number 12–33 (within-gene range 8–33): RPL6P25, AC090680.1, AC093025.1, AC090679.3, AC090679.2, AC090679.1, AC087888.1, AC093027.1, SLC6A15, AC128657.1, TSPAN19, LRRIQ1, ALX1, LINC02820, AC126471.1, AC137768.1, RASSF9, NTS, MGAT4C, AC016993.1, AC139697.1.
- chr12:89,919,437–90,112,779, 3 genes, copy number 23: BRWD1P2, LINC02399, AC126178.1.
- chr12:93,542,022–93,894,840, 7 genes, copy number 35 (within-gene range 4–35): SOCS2-AS1, SOCS2, AC012085.1, CRADD, AC012085.2, RN7SL630P, AC012464.2.
- chr12:94,306,449–95,073,628, 16 genes, copy number 9 (within-gene range 4–9): CEP83, RN7SL330P, RBMS2P1, CEP83-DT, AC023161.1, RN7SL483P, NSA2P2, SUCLG2P2, MIR5700, TMCC3, MIR7844, LSM3P2, KRT19P2, MIR492, NDUFA12, NR2C1.
- chr12:95,100,531–95,126,389, 2 genes, copy number 9: AC126615.2, AC126615.1.
- chr12:96,060,024–96,269,824, 6 genes, copy number 26: YPEL5P3, RN7SL88P, LINC02452, ELK3, AC008149.1, AC008149.2.
- chr12:103,746,315–103,965,708, 8 genes, copy number 21–29 (within-gene range 4–29): AC025265.1, NT5DC3, AC012555.2, AC012555.1, TTC41P, HSP90B1, MIR3652, C12orf73.
- chr15:95,326,528–101,933,350, 151 genes, copy number 10–26 (within-gene range 8–26) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 123. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
